Somatic mutation profile of tumor specimen TCGA-ER-A19C-06A (aliquot TCGA-ER-A19C-06A-11D-A196-08) from TCGA case TCGA-ER-A19C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 81.5 years (29,755 days).
Specimen TCGA-ER-A19C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8412ea5e-8678-41be-894d-b455a663d323.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19C-10A (Blood Derived Normal), aliquot TCGA-ER-A19C-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a234bfc-edc4-4d31-8ce7-a73bb4499aa0

The open-access MAF lists 103 somatic variants for this specimen: 55 protein-altering or splice-affecting, 45 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 45, RNA 3, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CHD2 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 127/207 reads (61%) | catalogued as rs1567138301, COSV59119573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.1606G>A p.A536T (on ENST00000219054; = p.A457T on NM_001308169.2) | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54588878; called by muse, mutect2, varscan2
- ACSS3 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV54099846; called by mutect2, varscan2
- ADAM29 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as COSV63667487; called by muse, varscan2
- ANK3 | c.5339C>T p.S1780L | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV55078208; called by muse, varscan2
- ANKRD30A | c.2770G>A p.D924N (on ENST00000611781; = p.D868N on NM_052997.2) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.419); catalogued as COSV64603707; called by muse, mutect2, varscan2
- ATP2A3 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV59234488; called by muse, mutect2, varscan2
- ATRNL1 | c.1583T>G p.L528R | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61814973; called by muse, mutect2, varscan2
- BRINP1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs139886257; called by mutect2, varscan2
- C1QA | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs45454296, COSV65890040; called by mutect2, varscan2
- C2CD3 | c.5639C>T p.T1880I | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV58099685; called by muse, mutect2, varscan2
- CASR | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56140916; called by muse, mutect2, varscan2
- CD163 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs1318743377, COSV63129120; called by muse, varscan2
- CNTNAP4 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 54/71 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as rs776534361, COSV56697845; called by muse, mutect2, varscan2
- COL3A1 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58589665; called by muse, mutect2, varscan2
- DACH1 | c.1793G>A p.G598E (on ENST00000619232 / NM_001366712.1; = p.G344E on NM_004392.6) | Missense Mutation (SNP) | VAF 102/262 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV57516906; called by muse, mutect2, varscan2
- DCAF11 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV58110566; called by muse, mutect2, varscan2
- DNAH17 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV67760341; called by mutect2, varscan2
- ELMOD1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 87/117 reads (74%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV56195725; called by muse, mutect2, varscan2
- ENPP7 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.629); catalogued as COSV60387696; called by muse, mutect2, varscan2
- FANCA | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66883461; called by muse, mutect2, varscan2
- FBXO42 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV65046704; called by muse, mutect2, varscan2
- FSTL5 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756146269, COSV60182341; called by muse, mutect2, varscan2
- GCNT4 | c.1138C>G p.P380A | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs201293154, COSV59281633; called by muse, mutect2, varscan2
- HS1BP3 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58314791; called by muse, mutect2, varscan2
- IL17A | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 118/328 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV60685353; called by muse, mutect2, varscan2
- IL5RA | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs769194828, COSV56526169; called by muse, mutect2, varscan2
- ILF2 | c.651G>C p.Q217H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62628035; called by muse, mutect2, varscan2
- LONRF2 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.47); PolyPhen benign (0.129); catalogued as rs894221703, COSV66539333; called by muse, mutect2, varscan2
- LSR | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as COSV61555857; called by muse, mutect2, varscan2
- LY9 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); catalogued as COSV54433709; called by muse, mutect2, varscan2
- MMRN1 | c.3158G>A p.G1053E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53341793; called by muse, mutect2, varscan2
- MYO18B | c.4759G>A p.D1587N | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306069007, COSV59133047, COSV59139313; called by muse, mutect2, varscan2
- NEK5 | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV62881670; called by muse, mutect2, varscan2
- NLRP7 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1355632267, COSV60172417; called by muse, mutect2, varscan2
- OR2F1 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV67331129; called by muse, mutect2, varscan2
- OSBP2 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs759374438, COSV60239551, COSV60248181; called by muse, mutect2, varscan2
- OTX2 | c.712C>T p.L238F (on ENST00000408990 / NM_172337.3; = p.L246F on NM_021728.4) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV59766739; called by muse, mutect2, varscan2
- PCDH17 | c.3050C>T p.P1017L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV64978313; called by muse, mutect2, varscan2
- PM20D1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65649556; called by muse, mutect2, varscan2
- PRDM1 | c.1916G>A p.R639K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64846779; called by muse, mutect2, varscan2
- RFX5 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); catalogued as COSV51841362; called by muse, mutect2, varscan2
- ROS1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 178/530 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs1307627482, COSV63854873; called by muse, mutect2, varscan2
- S100A9 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV64199857; called by muse, mutect2, varscan2
- SCN5A | c.2368A>C p.I790L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV61138951; called by muse, mutect2, varscan2
- SH3GL2 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV66054510; called by muse, mutect2, varscan2
- SP140 | c.1865G>T p.W622L | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as rs766427310, COSV59454332; called by mutect2, varscan2
- TCHH | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.607); catalogued as rs771536173, COSV64277413; called by mutect2, varscan2
- TMEM161B | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1253883836, COSV56929140; called by muse, mutect2, varscan2
- UGT1A8 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 83/147 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV65084893; called by muse, mutect2, varscan2
- USH2A | c.3920C>T p.S1307L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as CM054170, COSV56378913; called by mutect2, varscan2
- ZBTB22 | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56472324; called by muse, mutect2, varscan2
- ZP2 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.018); catalogued as COSV54814330; called by muse, mutect2, varscan2
- CASP8AP2 | c.4603_4605del p.E1535del | In Frame Del (DEL) | VAF 42/103 reads (41%) | called by mutect2, pindel, varscan2
- AC097636.1 | c.105G>A p.K35= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV71309644; called by muse, mutect2, varscan2
- ADAMTS16 | c.1290C>T p.T430= | Silent (SNP) | VAF 72/167 reads (43%) | catalogued as COSV57004949, COSV99940939; called by muse, mutect2, varscan2
- AFP | c.732T>C p.S244= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV56926796; called by muse, mutect2, varscan2
- BRINP3 | c.288C>T p.F96= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs867310371, COSV66511698, COSV66528585; called by muse, mutect2, varscan2
- CACNA1A | c.4695C>T p.F1565= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs377082780; called by mutect2, varscan2
- CACNA1B | c.4026G>A p.K1342= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV53145250; called by muse, mutect2, varscan2
- CCAR1 | c.411C>T p.S137= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV56273691; called by muse, mutect2, varscan2
- CFAP300 | c.201C>T p.F67= | Silent (SNP) | VAF 30/42 reads (71%) | catalogued as COSV71570952; called by mutect2, varscan2
- CNR2 | c.603C>T p.L201= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV65694365; called by muse, mutect2, varscan2
- DNAH5 | c.6624C>T p.L2208= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as COSV54247917, COSV54252061; called by muse, mutect2, varscan2
- DNAJB11 | c.1017C>T p.I339= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV54003599; called by mutect2, varscan2
- DNAJB5 | c.675C>T p.I225= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV56627283; called by mutect2, varscan2
- DSCAM | c.5760G>A p.R1920= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs765614344, COSV68034591; called by muse, mutect2
- EGFR | c.2991C>T p.F997= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV51837327, COSV51840483; called by muse, mutect2, varscan2
- EPHA6 | c.525A>G p.P175= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV67591248; called by muse, varscan2
- ERICH6 | c.1224C>T p.I408= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs776165623, COSV55802862; called by mutect2, varscan2
- FAM47C | c.2562C>T p.D854= | Silent (SNP) | VAF 54/75 reads (72%) | catalogued as COSV63729909; called by muse, mutect2, varscan2
- FARP2 | c.645G>T p.S215= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99885687; called by muse, mutect2, varscan2
- GABRP | c.432C>T p.S144= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV54665372; called by muse, mutect2, varscan2
- GBP5 | c.651C>T p.F217= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV58594146; called by mutect2, varscan2
- IGHV3-20 | c.183G>A p.G61= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs550061710; called by muse, mutect2, varscan2
- KCNQ1 | c.705C>T p.I235= | Silent (SNP) | VAF 104/145 reads (72%) | catalogued as rs1057521015, COSV50126329; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRGUK | c.2451C>T p.L817= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99604765; called by muse, mutect2
- LRP5 | c.3333C>T p.L1111= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs755416405, COSV53722659; called by mutect2, varscan2
- MAP3K3 | c.396C>T p.P132= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs371965403; called by muse, mutect2, varscan2
- OR10A4 | c.771C>T p.I257= | Silent (SNP) | VAF 55/73 reads (75%) | catalogued as COSV65842392; called by muse, mutect2, varscan2
- OR2D2 | c.531C>T p.F177= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV55057196; called by muse, mutect2, varscan2
- OR2G6 | c.681G>A p.R227= | Silent (SNP) | VAF 72/124 reads (58%) | catalogued as COSV58575664; called by muse, mutect2, varscan2
- OR4A47 | c.135G>A p.V45= | Silent (SNP) | VAF 26/38 reads (68%) | catalogued as COSV71445124; called by muse, mutect2, varscan2
- PCSK9 | c.1548G>A p.G516= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as rs557227031, COSV56164394; called by muse, mutect2, varscan2
- PEG3 | c.4407G>A p.E1469= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV55645186; called by muse, mutect2, varscan2
- PHOX2B | c.177C>T p.S59= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV56931306; called by muse, mutect2
- PTPRD | c.3763C>T p.L1255= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV100643894, COSV61976202; called by muse, mutect2, varscan2
- SCN3B | c.216C>T p.F72= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as COSV54799202, COSV54800245; called by muse, varscan2
- SCN9A | c.2100G>A p.V700= (on ENST00000303354; = p.V689= on NM_002977.3) | Silent (SNP) | VAF 41/77 reads (53%) | catalogued as COSV100314417; called by muse, mutect2, varscan2
- SEMA4B | c.177C>T p.F59= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60175604; called by muse, mutect2
- SH3RF2 | c.546C>T p.I182= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV63041077; called by mutect2, varscan2
- SLC9C2 | c.795C>T p.F265= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV62943813, COSV62948813; called by muse, mutect2, varscan2
- SPINT2 | c.645C>T p.A215= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV56648888; called by muse, varscan2
- STK31 | c.1686C>T p.V562= | Silent (SNP) | VAF 62/176 reads (35%) | catalogued as rs1390948704, COSV63458954; called by muse, mutect2, varscan2
- SYNE1 | c.5154A>G p.Q1718= (on ENST00000367255 / NM_182961.4; = p.Q1725= on NM_033071.3) | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV55081875; called by muse, mutect2, varscan2
- TICAM1 | c.1146C>T p.F382= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV50229813, COSV50230412; called by muse, mutect2, varscan2
- UGT2B4 | c.81G>A p.L27= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV100522641, COSV59316195, COSV59319988; called by muse, mutect2, varscan2
- UGT3A1 | c.33C>T p.A11= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV57102334; called by muse, varscan2
- UNC79 | c.7515G>A p.A2505= (on ENST00000393151 / NM_001346218.2; = p.A2328= on NM_020818.5) | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as rs758974627, COSV56407002; called by mutect2, varscan2
- CCNQP1 | n.308C>T | RNA (SNP) | VAF 29/64 reads (45%) | catalogued as rs1243064532; called by muse, mutect2, varscan2
- MIR573 | n.1T>A | RNA (SNP) | VAF 50/149 reads (34%) | called by muse, mutect2, varscan2
- SNORD115-8 | n.55C>T | RNA (SNP) | VAF 94/163 reads (58%) | called by muse, varscan2
